Gene-level copy-number profile of tumor specimen TCGA-44-6147-01A from TCGA case TCGA-44-6147, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.4 years (24,631 days).
Specimen TCGA-44-6147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b7413d59-4651-486e-9bad-60a630313b7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-6147-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files).
https://portal.gdc.cancer.gov/files/f020bf5a-01c3-47f5-b0cd-e85f04f51ad4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,173; copy number 2: 26,805; copy number 3: 15,881; copy number 4: 7,582; copy number 5: 2,724; copy number 6: 56; copy number 7: 1,593.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-44-6147-01): tumor purity 0.47, ploidy 1.93, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,373 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr8:38,728,186–38,853,028, 1 gene, copy number 6 (within-gene range 4–6): TACC1.
- chr8:38,799,643–145,066,685, 1,648 genes, copy number 6–7 (broad region; genes not listed).
- chr14:40,630,006–42,989,483, 16 genes, copy number 5 (within-gene range 3–5): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1.
- chr14:72,022,407–72,022,516, 1 gene, copy number 5: Y_RNA.
- chr14:78,170,373–79,868,291, 1 gene, copy number 5 (within-gene range 3–5): NRXN3.
- chr14:78,231,281–81,221,377, 25 genes, copy number 5 (within-gene range 3–5): RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1, AC026888.1, AC022469.1, AC022469.2, AC008056.2, AC008056.3, AC008056.1, AF123462.1, DIO2, DIO2-AS1, CEP128, HMGN2P2, TSHR, BHLHB9P1, RPL17P3, AC007262.1, AC007262.2, NMNAT1P1, AL136040.2, GTF2A1, SNORA79.
- chr20:10,672,695–11,878,429, 17 genes, copy number 5 (within-gene range 4–5): AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1.
- chr20:19,693,209–20,056,046, 6 genes, copy number 5: AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.
- chr20:20,094,401–20,095,684, 1 gene, copy number 5: AL035454.1.
- chr20:38,127,385–40,758,636, 53 genes, copy number 5 (within-gene range 4–5): TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2.

Autosomal genes at a single copy (total copy number 1): 5,173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
